Somatic mutation profile of tumor specimen TCGA-EL-A3GW-01A (aliquot TCGA-EL-A3GW-01A-11D-A202-08) from TCGA case TCGA-EL-A3GW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.4 years (13,670 days).
Specimen TCGA-EL-A3GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c91c748-4ec8-428c-8b2d-d3cd4822bd16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GW-10A (Blood Derived Normal), aliquot TCGA-EL-A3GW-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa2cd78c-f24f-437f-ac8c-09627e2b8e8e

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 85/171 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD9 | c.6726G>T p.E2242D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as COSV54608640; called by muse, mutect2, varscan2
- FANCG | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV66213550; called by muse, mutect2, varscan2
- MAPKAPK3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as rs754225374, COSV63597041; called by muse, mutect2, varscan2
- MED31 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV56725883; called by muse, mutect2
- NPHS1 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.462); catalogued as rs374846352; called by muse, mutect2, varscan2
- TAB3 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55835293; called by muse, mutect2, varscan2
- DBNL | c.111C>T p.S37= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV68880498; called by muse, mutect2
- MED6 | c.711C>T p.G237= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs758929560, COSV56449702; called by muse, mutect2
- TNPO3 | c.789G>A p.L263= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs765394864, COSV55279194; called by muse, mutect2, varscan2
